CGCI case HTMCP-01-16-00267 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cec36378-1d69-489e-bc09-ad8613e80e3e

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 53 years; Vital status: Dead; Days to death: 803 days (2.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 53.7 years (19,616 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 803 days (2.2 years); Max tumor bulk site: Oropharynx; Sites of involvement: Nasopharynx / Oropharynx.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Lymph node involved site: Mediastinal.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Days to follow up: 498 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 600 days (1.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 600 days (1.6 years).
- Days to follow up: 803 days (2.2 years); Disease response: Tumor Free.
- Imaging type: PET; Imaging result: Negative.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL2: Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD10: Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD30: Negative.
- CD5: Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- IRF4: Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Test: Negative; Specialized molecular test: EBER.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Weight: 82 kg; Height: 170 cm; BMI: 28.4; CD4 count: 159; Haart treatment indicator: No.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Biospecimens (3 samples)
- Sample HTMCP-01-16-00267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-16-00267-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-16-00267-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lost to follow-up: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Nasopharynx.
- Primary pathology: Method initial path diagnosis: Biopsy (all types).
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: Eber.
- Tests performed: Ebv status malignan cells method: EBER in situ hybridization.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Cause of death: Non-Cancer Related; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00267-01A-01E-13312:
- % tumour top: 80
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-16-00267-01A-01S-13312:
- % tumour top: 80
- % tumour bottom: 70
